TARGET case TARGET-40-NAAGKA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ac4744d-274d-571b-829d-e7a87403a65d

Demographics
Sex at birth: female; Race: asian; Age at index: 11 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 11.8 years (4,298 days); Year of diagnosis: 1997; Metastasis at diagnosis: No Metastasis; Days to last follow up: 5,302 days (14.5 years).
   Pathology details: Necrosis percent: 80.

Follow-up (1 entry)
- Days to follow up: 5,302 days (14.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 5,302; Year of follow up: 2012.

Biospecimens (1 sample)
- Sample TARGET-40-NAAGKA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGKA-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 45
- % Non Tumor Nuclei: Top from Biopsy: 55
- % Cellular Tumor: Top from Biopsy: 10
- % Normal: Top from Biopsy: 35
- % Stroma: Top from Biopsy: 10
- % Necrosis: Top from Biopsy: 45

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 5302
- Protocol: Other osteosarcoma
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
